Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NV, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NV-01A (Primary Tumor).

ICD-0-3
Carcinoma, hepatocellular
NOS
8170/3
Site: Liver C22.0

9/12/24/12

TISSUE DESCRIPTION:

A1 B1 B2 B3 B4 B5 B6 B7 B8 B9 B10 B11 B12 B13

Tissue from liver segment VI (needle core biopsy, two cores, 1.3 cm in length and 1.5 cm in length) and separately submitted liver segments V and VI (resection, 1445.0 grams, 21.4 x 13.8 x 11.4 cm).

DIAGNOSIS:

Liver, segments V and VI, resection: Grade 1 to 2 (of 4) hepatocellular carcinoma forming multiple (2) masses (1.7 x 1.6 x 1.5 cm and 11.8 x 11.3 x 10.2 cm) located 0.9 cm to the nearest negative surgical resection margin. Also present, are multiple (6) bile duct hamartomas (ranging in size from 0.2 cm to 0.4 cm in greatest dimension). The surrounding hepatic parenchyma displays steatohepatitis.

Liver, segment VI, needle core biopsy: Grade 1 to 2 (of 4) hepatocellular carcinoma.

Case ID (circle)		

9/20/12

Source: NCI Genomic Data Commons file be1c33a5-959f-459b-8fee-dacad28777cd (TCGA-DD-A4NV.C65CD25A-D623-4793-B22F-567693666073.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).